Somatic mutation profile of tumor specimen TARGET-30-PATYEJ-01A (aliquot TARGET-30-PATYEJ-01A-01D) from TARGET case TARGET-30-PATYEJ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.2 years (1,177 days).
Specimen TARGET-30-PATYEJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afa8e671-0adf-4f2c-a995-8a942dad851f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATYEJ-10A (Blood Derived Normal), aliquot TARGET-30-PATYEJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/080b3f3f-381b-4227-90d7-0075ca65256e

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.1900C>A p.Q634K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- MET | c.3913C>T p.P1305S | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF3 | c.*58G>T | 3'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
